Surgical pathology report (de-identified scan), TCGA case TCGA-56-7580, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-7580-01A (Primary Tumor).

[page 1 of 3]
Surg Path Final Report

* Final Report *

* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:
Accession:
Physician:

PROCEDURE

Biopsy.

SPECIMEN:

- A. Left lower lobe wedge. B. Section of L. upper lobe wedge.
C. AP window node.

HISTORY

squamous cell carcinoma left lower lobe; check margins.

GROSS

A. Specimen received in fresh for frozen section labeled as "left lower lobe wedge" consists of a fragment of lung measuring 7 x 5.5 x 3.8 cm and weighing 56.5 grams. There is a nodule measuring 3.5 cm, subpleural, with a firm yellow-tan-gray variegated appearance and necrosis. Representatively processed for frozen section.

Grossly, the resection margin is free of tumor, 1.6 cm from the tumor. The pleura closest distance to tumor measures 0.1 cm. Representatively submitted as follows:

1. Frozen section control
- 2-4. Tumor.

B. Received in formalin in a container labeled "section of left upper lobe wedge" is a wedge of purple-tan lung (4.5 x 1 x 0.6 cm) with a stapled margin. The pleural surface is smooth and marked with blue ink. The specimen is serially sectioned and submitted in its entirety in one cassette.

C. Received in formalin in a container labeled "AP window node" is a 1.6 cm in greatest dimension, rough-surfaced anthracotic lymph node accompanied by three fragments of anthracotic adipose tissue (0.4-0.6 cm). The node is bisected. The tissue is submitted in its entirety in one cassette.

FROZEN SECTION DIAGNOSIS

- A. Squamous cell carcinoma. Dr. is noted for diagnosis at

[page 2 of 3]
[REDACTED]

MICROSCOPIC
Performed.

DIAGNOSIS

Left lower lobe lung, wedge resection:

Squamous cell carcinoma (previously diagnosed, [REDACTED], poorly differentiated, nonkeratinizing, with tumor necrosis (3.5 cm).

Resection margin grossly free of tumor. [REDACTED]

SUMMARY OF MALIGNANT NEOPLASM: LUNG

SPECIMEN: lung wedge
PROCEDURE: wedgectomy
SPECIMEN INTEGRITY: intact
SPECIMEN LATERALITY: left
TUMOR SITE: lower lobe
TUMOR SIZE: 3.5 cm
TUMOR FOCALITY: Unifocal
HISTOLOGIC TYPE: Squamous cell carcinoma
HISTOLOGIC GRADE: Poorly differentiated
VISCERAL PLEURA INVASION: No visceral pleural involvement
MARGINS: Uninvolved. 1.6 cm to closest margin
TREATMENT EFFECT: Not applicable
LYMPH-VASCULAR INVASION: Not identified
LYMPH NODES: N/A
OTHER FINDINGS: Thick-walled parenchymal blood vessels;
tumor necrosis; septal fibrosis.
PATH TNM(AJCC 7th ed.): pT2a pN0 Stage IB

COMMENT

Permanent section confirms the frozen section diagnosis.
Case shown in consultation to Dr. Jin, who concurs with the diagnosis.

[REDACTED]

[REDACTED]

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 3752f78b-1f47-4735-b25a-6741f9d02a15 (TCGA-56-7580.B1697486-2A16-4466-8F2F-7F2CB7676563.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).